CCDI case PBBWHN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/3ca33846-5cf2-4948-b4e7-60196b101c01

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.5 years (2,359 days).

Biospecimens (3 samples)
- Sample 0DJ8JK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJ8KJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJ8KR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
